Somatic mutation profile of tumor specimen TCGA-DB-A64U-01A (aliquot TCGA-DB-A64U-01A-11D-A29Q-08) from TCGA case TCGA-DB-A64U, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 38.4 years (14,019 days).
Specimen TCGA-DB-A64U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4747bf1-3652-4181-9d8f-26505439fa6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-A64U-10A (Blood Derived Normal), aliquot TCGA-DB-A64U-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7d4a139-91b9-4146-a9ab-f42449cb863d

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 4, Silent 4, Frame Shift Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.4535G>A p.R1512H | Missense Mutation (SNP) | VAF 37/76 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50554672, COSV50623937; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CTPS2 | c.1759T>A p.*587Rext*13 | Nonstop Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as COSV63724733; called by muse, mutect2, varscan2
- KIAA1549L | c.4031A>G p.N1344S (on ENST00000321505; = p.N1641S on NM_012194.3) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.85); PolyPhen benign (0.012); catalogued as rs377520713, COSV58597530; called by muse, mutect2, varscan2
- PDE3A | c.1843A>G p.T615A | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs113434458, COSV62984318; called by muse, varscan2
- SERAC1 | c.1448del p.R483Kfs*35 | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | called by mutect2, pindel, varscan2
- EHMT2 | c.3207G>A p.G1069= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as COSV57669498; called by muse, mutect2, varscan2
- PDE6B | c.2550C>A p.T850= | Silent (SNP) | VAF 41/161 reads (25%) | catalogued as COSV55331782; called by muse, mutect2, varscan2
- SEC14L1 | c.519A>G p.E173= | Silent (SNP) | VAF 15/122 reads (12%) | catalogued as COSV66726138; called by mutect2, varscan2
- ZW10 | c.1938G>T p.V646= | Silent (SNP) | VAF 74/107 reads (69%) | catalogued as COSV52317110, COSV52320062; called by muse, mutect2, varscan2
